Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1IA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1IA-06A (Metastatic).

SURGICAL PATHOLOGY REPORT

1CD-0-3

Melanoma, NOS 8720/3

Site: Brain, frontal lobe C71.1

3/12/11 hu

Clinical History and Impression:

Brain mets.

year old female with melanoma met to right frontal lobe

Specimen(s) Received:
RIGHT FRONTAL TUMOR

FINAL DIAGNOSIS

BRAIN, "RIGHT FRONTAL TUMOR", BIOPSY:

- METASTATIC MALIGNANT MELANOMA, SEE NOTE.

NOTE: Per clinical history, the patient has a history of primary melanoma elsewhere. Previously resected tumor material is not available for review.

Pathologist: , M.D.
* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

M.D. ; M.D., Ph.D.)

Received fresh in a container, isoprep with the patient's name and "right frontal tumor" are multiple fragments of soft tissue measuring in aggregate 2.2 x 1.0 x 0.6 cm. The tissue is dark brown with areas of hemorrhage. The specimen reveals no gross mass. The specimen is entirely submitted in two cassettes.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

Part 1) RIGHT FRONTAL TUMOR	# Blocks	Designation	#	Description
	2	BRAIN	(2)	(No Description)

END OF REPORT

Source: NCI Genomic Data Commons file dab6f641-2844-4fe0-8b79-3a5cbd377269 (TCGA-DA-A1IA.A8C5B4DF-C8BD-43FF-9613-04942F68DCAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).